Somatic mutation profile of tumor specimen TCGA-DX-A6YX-01A (aliquot TCGA-DX-A6YX-01A-11D-A417-09) from TCGA case TCGA-DX-A6YX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 68.1 years (24,871 days).
Specimen TCGA-DX-A6YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0d8947-eab9-494f-9c02-fed7e8f0cb13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YX-10B (Blood Derived Normal), aliquot TCGA-DX-A6YX-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b271d8a-ffbc-47f2-ba5e-a355bb76a6d3

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM11 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs1185052316, COSV99567929; called by muse, mutect2
- ATP10B | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100469905; called by muse, mutect2, varscan2
- CCDC127 | c.30G>C p.W10C | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99372295; called by mutect2, varscan2
- CFAP46 | c.7202G>A p.R2401Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375364632, COSV99583945; called by muse, mutect2, varscan2
- DCAF10 | c.1219A>T p.S407C | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99647966; called by muse, mutect2, varscan2
- EPHA3 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100349524, COSV60706391; called by muse, varscan2
- FGD1 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV100911279; called by muse, mutect2
- GBA2 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.129); catalogued as rs1176220861, COSV100803548; called by muse, mutect2, varscan2
- KIAA0319L | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs748599916, COSV100357804; called by muse, mutect2, varscan2
- LILRB5 | c.299A>C p.Y100S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV100300914; called by muse, mutect2, varscan2
- MAGEB4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV100854628, COSV64397035; called by muse, mutect2, varscan2
- MUC16 | c.36745C>T p.R12249C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs760969863, COSV101198191; called by muse, mutect2, varscan2
- OAS3 | c.2119A>G p.N707D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV99966639; called by muse, varscan2
- PCDHAC2 | c.1231C>G p.R411G | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs551685820, COSV99163568; called by muse, mutect2, varscan2
- PTPRZ1 | c.707C>A p.T236K | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101100928; called by muse, mutect2, varscan2
- RHOXF2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.334); catalogued as rs782294784, COSV65047684; called by muse, mutect2, varscan2
- RP1L1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV101223770; called by muse, mutect2, varscan2
- SCN2A | c.4735G>A p.V1579M | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99333931; called by muse, mutect2, varscan2
- SCN4A | c.5337G>C p.M1779I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV101438706; called by muse, mutect2, varscan2
- SH3BGRL | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100943519; called by muse, mutect2, varscan2
- SMURF2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782611657, COSV99301209; called by muse, mutect2, varscan2
- TMEM71 | c.424C>T p.P142S (on ENST00000523829 / NM_001382398.1; = p.P123S on NM_144649.3) | Missense Mutation (SNP) | VAF 127/203 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.134); catalogued as COSV100785721; called by muse, mutect2, varscan2
- TNFAIP1 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs879949673, COSV99134882; called by muse, mutect2, varscan2
- VPS54 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99708918; called by muse, mutect2
- CTNNA3 | c.1394del p.A465Vfs*33 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | called by mutect2, pindel, varscan2
- FLNC | c.3905_3908del p.T1302Mfs*2 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- DOCK2 | c.4950C>T p.S1650= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs761874305, COSV56985461; called by muse, mutect2, varscan2
- KIF13B | c.3678C>T p.S1226= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV101580860; called by muse, mutect2, varscan2
- KIF4B | c.1179G>A p.Q393= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV101469428; called by muse, mutect2, varscan2
- LHFPL1 | c.309C>T p.V103= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100914534; called by muse, mutect2, varscan2
- MAP3K10 | c.2757G>A p.P919= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs762024472, COSV99454293; called by muse, mutect2, varscan2
- MYO15A | c.1050C>T p.D350= | Silent (SNP) | VAF 43/50 reads (86%) | catalogued as rs772046274, COSV52757042; called by muse, mutect2, varscan2
- RGS6 | c.243A>C p.A81= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100667183; called by muse, mutect2, varscan2
- SOGA1 | c.1989C>T p.V663= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99415876; called by muse, mutect2, varscan2
- UGT2A1 | c.795T>C p.P265= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99685017; called by muse, mutect2, varscan2
- USP17L2 | c.1245C>T p.L415= | Silent (SNP) | VAF 61/95 reads (64%) | catalogued as COSV100414799, COSV61555865; called by muse, mutect2, varscan2
- USP17L2 | c.774C>G p.L258= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV100414673, COSV100414801; called by muse, varscan2
- VPS4A | c.798G>A p.L266= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as COSV99652184; called by muse, mutect2, varscan2
- ZNRF4 | c.937C>T p.L313= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1414380994, COSV99706781; called by muse, mutect2
- SNORD115-25 | n.55C>T | RNA (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
